TCGA case TCGA-WB-A81Q — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Adrenal gland; Tissue source site: Erasmus MC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b5b31686-995b-433a-afab-6eee027817ba

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 44 years; Vital status: Dead; Days to death: 755 days (2.1 years).

Diagnoses (2)
1. Pheochromocytoma, malignant (the primary disease): ICD-O-3 morphology code: 8700/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Site of resection or biopsy: Adrenal gland, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 45.0 years (16,422 days); Year of diagnosis: 1997; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 123 days; Days to treatment end: 551 days (1.5 years); Treatment dose: 310 mCi; Treatment outcome: Progressive Disease; Number of fractions: 2.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Dacarbazine + Vincristine; Days to treatment start: 620 days (1.7 years); Days to treatment end: 704 days (1.9 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 707 days (1.9 years); Days to treatment end: 749 days (2.1 years); Treatment outcome: Progressive Disease.
2. Pheochromocytoma, NOS: ICD-O-3 morphology code: 8700/0; Tissue or organ of origin: Liver; Classification of tumor: Synchronous primary; Age at diagnosis: 45.0 years (16,422 days).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -15 days; Treatment anatomic sites: Liver.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cyclophosphamide + Dacarbazine + Gemcitabine + Vincristine; Days to treatment start: 707 days (1.9 years); Treatment anatomic sites: Body, total.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment anatomic sites: Body, total.

Follow-up (2 entries)
- Day 0 (prior to diagnosis): History of tumor: No; History of tumor type: Phenochromocytoma or Paraganglioma.
- Days to follow up: 755 days (2.1 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WB-A81Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-WB-A81Q-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WB-A81Q-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WB-A81Q-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: No; History neoadjuvant treatment: No; Tumor status: With tumor; New tumor event diagnosis indicator: No.
- Primary pathology: Related tumors outside adrenal glands: Multiple tumors outside the adrenal glands; Histologic diagnosis: Pheochromocytoma; Disease detected on screening: No; Ct scan preop results: Yes; Lymph nodes examined: No.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Liver; Other malignancy histological type: pheochromocytoma.
- Other malignancy form, Surgery: Other malignancy surgery type: intra-operative liver biopsy.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Systemic.
- Other malignancy form, Drug treatment, Administered drug 2: Pharmaceutical therapy drug name: Cyclophosphamid.
- Other malignancy form, Drug treatment, Administered drug 3: Pharmaceutical therapy drug name: Dacarbazin.
- Other malignancy form, Drug treatment, Administered drug 4: Pharmaceutical therapy drug name: vincristin.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Systemic.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 755 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 755 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 755 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WB-A81Q-01A-11D-A35H-01): tumor purity 0.88, ploidy 1.94, whole-genome doublings 0.
